Somatic mutation profile of tumor specimen MMRF_2237_1_BM_CD138pos (aliquot MMRF_2237_1_BM_CD138pos_T1_KHS5U_L09548) from MMRF case MMRF_2237, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 46.1 years (16,829 days).
Specimen MMRF_2237_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8cbcf8c-d2c9-410b-834a-a795e8953772.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2237_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2237_1_PB_Whole_C2_KHS5U_L09549; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1bc4378a-f92c-422a-ab9e-06c392b5aea4

The open-access MAF lists 60 somatic variants for this specimen: 25 protein-altering or splice-affecting, 6 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, 3'UTR 17, Intron 8, Silent 6, 5'UTR 2, 5'Flank 1, Frame Shift Del 1, RNA 1, Frame Shift Ins 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 105/175 reads (60%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF17 | c.3643C>T p.R1215C | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1276766339, COSV55233072; called by muse, mutect2, varscan2
- IGHV2-70 | c.152G>C p.S51T | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs372640551; called by muse, varscan2
- IGHV2-70 | c.64A>G p.T22A | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as rs755395069; called by muse, varscan2
- IGKJ4 | c.31A>T p.I11F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | PolyPhen benign (0.034); catalogued as rs139461207; called by muse, varscan2
- IGLL5 | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.284); catalogued as rs779042230, COSV104440278, COSV104440315; called by muse, mutect2, varscan2
- IGLV3-1 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 131/209 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as rs61736463; called by muse, mutect2, varscan2
- LHX8 | c.1063C>A p.H355N | Missense Mutation (SNP) | VAF 20/441 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.954); catalogued as COSV53959202; called by muse, mutect2
- NRXN2 | c.2422G>A p.G808S | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as rs1296267822, COSV99634988; called by muse, mutect2, varscan2
- OBSCN | c.4697C>T p.T1566M | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as rs56217040, COSV52758702; called by muse, mutect2, varscan2
- PRODH2 | c.907-8G>A | Splice Region (SNP) | VAF 17/56 reads (30%) | catalogued as rs923013604; called by muse, mutect2, varscan2
- PTH | c.289del p.S97Vfs*10 | Frame Shift Del (DEL) | VAF 130/407 reads (32%) | catalogued as rs780166894; called by mutect2, pindel, varscan2
- TKTL2 | c.617G>T p.C206F | Missense Mutation (SNP) | VAF 80/172 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV99761645; called by muse, mutect2, varscan2
- TM9SF4 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770747344; called by muse, mutect2, varscan2
- TTC16 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 53/208 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766174448, COSV64778321; called by muse, mutect2, varscan2
- TTC39C | c.1303C>T p.R435* (on ENST00000317571 / NM_001135993.2; = p.R374* on NM_153211.4) | Nonsense Mutation (SNP) | VAF 22/121 reads (18%) | catalogued as rs140461929; called by muse, mutect2, varscan2
- BANF1 | c.92G>A p.G31D | Missense Mutation (SNP) | VAF 163/247 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- LRRTM3 | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- NXT1 | c.333G>T p.Q111H | Missense Mutation (SNP) | VAF 7/159 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- PTPN13 | c.4654G>A p.D1552N (on ENST00000411767 / NM_080683.3; = p.D1533N on NM_006264.3) | Missense Mutation (SNP) | VAF 119/244 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RALGAPA1 | c.5582dup p.N1861Kfs*29 | Frame Shift Ins (INS) | VAF 16/40 reads (40%) | called by mutect2, varscan2
- SCP2 | c.875C>G p.S292C | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- SKP2 | c.167T>A p.L56H | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2
- THEM5 | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- UROC1 | c.1264G>A p.G422S | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CLDN20 | c.147G>A p.G49= | Silent (SNP) | VAF 54/114 reads (47%) | called by muse, mutect2, varscan2
- DUSP2 | c.343C>T p.L115= | Silent (SNP) | VAF 45/97 reads (46%) | catalogued as rs542663886; called by muse, mutect2, varscan2
- IFNGR2 | c.657C>T p.N219= | Silent (SNP) | VAF 60/138 reads (43%) | called by muse, mutect2, varscan2
- IGHV1-24 | c.66G>A p.Q22= | Silent (SNP) | VAF 52/55 reads (95%) | catalogued as rs147067511; called by muse, mutect2, varscan2
- MIXL1 | c.117G>A p.L39= | Silent (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- NRTN | c.396C>T p.G132= | Silent (SNP) | VAF 26/112 reads (23%) | called by muse, mutect2, varscan2
- AC092647.5 | c.268+123dup | Intron (INS) | VAF 8/26 reads (31%) | called by mutect2, varscan2
- CRTAC1 | c.1819+1724del | Intron (DEL) | VAF 33/78 reads (42%) | catalogued as rs1407090349; called by mutect2, pindel, varscan2
- CSTB | c.*133C>T | 3'UTR (SNP) | VAF 171/389 reads (44%) | called by muse, mutect2, varscan2
- DNAH5 | c.*45C>A | 3'UTR (SNP) | VAF 82/310 reads (26%) | called by muse, mutect2, varscan2
- ELF2 | c.*530A>G | 3'UTR (SNP) | VAF 34/106 reads (32%) | called by muse, varscan2
- FADS6 | c.412-36_412-31dup | Intron (INS) | VAF 65/132 reads (49%) | called by mutect2, varscan2
- FAM207BP | n.387C>G | RNA (SNP) | VAF 9/15 reads (60%) | called by muse, mutect2, varscan2
- FOXJ1 | c.*33C>T | 3'UTR (SNP) | VAF 4/14 reads (29%) | called by muse, varscan2
- IGKV2-30 | c.-14T>A | 5'UTR (SNP) | VAF 23/46 reads (50%) | called by muse, mutect2, varscan2
- KIF3B | c.*213C>T | 3'UTR (SNP) | VAF 43/84 reads (51%) | called by muse, mutect2, varscan2
- LIMD1 | chr3:45594572 G>A | 5'Flank (SNP) | VAF 10/123 reads (8%) | called by muse, mutect2
- LYPLA1 | c.*1125C>T | 3'UTR (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- MAP7D1 | c.2025+36C>T | Intron (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
- OTP | c.*177del | 3'UTR (DEL) | VAF 21/49 reads (43%) | called by mutect2, pindel, varscan2
- PCDH11Y | c.*2371T>C | 3'UTR (SNP) | VAF 11/178 reads (6%) | called by muse, mutect2
- PRKACB | c.47-14863_47-14858del | Intron (DEL) | VAF 149/323 reads (46%) | called by mutect2, pindel, varscan2
- QKI | c.*612G>T | 3'UTR (SNP) | VAF 38/79 reads (48%) | called by muse, mutect2, varscan2
- SAMD14 | c.1099-40G>C | Intron (SNP) | VAF 61/177 reads (34%) | catalogued as rs559765699; called by muse, mutect2, varscan2
- SFRP1 | c.*2636T>G | 3'UTR (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- SH3TC2 | c.*599A>G | 3'UTR (SNP) | VAF 18/61 reads (30%) | called by muse, mutect2, varscan2
- SMARCE1 | c.*2430T>C | 3'UTR (SNP) | VAF 18/77 reads (23%) | called by muse, mutect2, varscan2
- SNN | c.*692T>G | 3'UTR (SNP) | VAF 24/106 reads (23%) | called by muse, mutect2, varscan2
- SPTBN1 | c.6420+1505C>T | Intron (SNP) | VAF 56/97 reads (58%) | catalogued as rs903502775; called by muse, mutect2, varscan2
- TTC7A | c.*1742G>T | 3'UTR (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- YAF2 | c.*89T>A | 3'UTR (SNP) | VAF 101/246 reads (41%) | called by muse, mutect2, varscan2
- YIF1A | c.642-163G>A | Intron (SNP) | VAF 65/103 reads (63%) | called by muse, mutect2, varscan2
- ZFP91 | c.*1426_*1428delinsCGCCGACAGATAGGATCC | 3'UTR (INS) | VAF 26/54 reads (48%) | called by pindel, varscan2*
- ZNF829 | c.*307C>T | 3'UTR (SNP) | VAF 43/220 reads (20%) | called by muse, mutect2, varscan2
- ZNF90 | c.-24T>C | 5'UTR (SNP) | VAF 144/319 reads (45%) | called by muse, mutect2, varscan2
